Somatic mutation profile of tumor specimen ALCH-B0HK-TTP1-A (aliquot ALCH-B0HK-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B0HK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.6 years (23,234 days).
Specimen ALCH-B0HK-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07b825d8-632b-4fc2-aa71-c1ade774e484.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0HK-NB1-A (Blood Derived Normal), aliquot ALCH-B0HK-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d76f5d1-41ca-4b46-bbec-73a2e7a8ba35

The open-access MAF lists 601 somatic variants for this specimen: 432 protein-altering or splice-affecting, 111 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 362, Silent 111, Nonsense Mutation 30, Intron 22, RNA 16, Splice Site 15, Frame Shift Del 14, 5'UTR 8, 3'UTR 7, Splice Region 6, 5'Flank 3, Nonstop Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS9 | c.1789+1G>A p.X597_splice (on ENST00000242067 / NM_001348036.1; = p.X557_splice on NM_014451.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 51/461 reads (11%) | catalogued as rs201938124, CS055613, COSV54176338; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FRMD7 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 103/571 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852212, CM074182, CM080375, COSV53745682, COSV53747620; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 41/192 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67959995, COSV67960100, COSV67961494; called by muse, mutect2, varscan2
- SATB2 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 106/570 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1085308028; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.4201G>A p.V1401M | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.54); catalogued as rs758164706, COSV60914578; called by muse, mutect2, varscan2
- AHRR | c.1347C>G p.I449M | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as rs779853326; called by muse, mutect2
- AL121899.2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 45/340 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV67350257; called by muse, mutect2, varscan2
- AMPH | c.210G>T p.M70I | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV57738162; called by muse, mutect2
- ANO8 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV50202364, COSV99344576; called by muse, mutect2, varscan2
- ARHGAP12 | c.1089+1G>A p.X363_splice | Splice Site (SNP) | VAF 8/146 reads (5%) | catalogued as rs1330778291; called by muse, mutect2
- ARHGAP35 | c.4302C>G p.F1434L | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV101351211; called by muse, mutect2
- ARHGAP36 | c.553C>A p.R185= | Splice Region (SNP) | VAF 36/189 reads (19%) | catalogued as COSV52273309; called by muse, mutect2, varscan2
- ATP10B | c.3237G>C p.Q1079H | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100515642; called by muse, mutect2, varscan2
- ATP7A | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100431616; called by muse, mutect2, varscan2
- BCORL1 | c.1477G>T p.V493L | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.3); catalogued as COSV54409920; called by muse, mutect2
- BIRC3 | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 57/337 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933852178; called by muse, mutect2, varscan2
- BPTF | c.6794G>T p.R2265L | Missense Mutation (SNP) | VAF 25/533 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1555671520; called by muse, mutect2
- C10orf71 | c.705C>A p.F235L | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV60504195; called by muse, mutect2
- C10orf71 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as COSV60505503; called by muse, mutect2
- C2CD4A | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs1277645940; called by muse, mutect2
- C7 | c.1586G>T p.S529I | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV57473987; called by muse, mutect2
- C8orf82 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as COSV52774787; called by muse, mutect2
- CACNA1E | c.5660G>A p.R1887K | Missense Mutation (SNP) | VAF 53/392 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV62429572; called by muse, mutect2, varscan2
- CCDC81 | c.176T>A p.F59Y | Missense Mutation (SNP) | VAF 47/403 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1302117483; called by muse, mutect2, varscan2
- CCR6 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV100551234; called by muse, mutect2
- CDH10 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 19/508 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.506); catalogued as COSV52575025; called by muse, mutect2
- CDH18 | c.1673G>T p.R558L | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV56912409, COSV56939656; called by muse, mutect2
- CDH26 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 48/415 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs1486282130; called by muse, mutect2, varscan2
- CDKN2A | c.150+1G>C p.X50_splice | Splice Site (SNP) | VAF 49/265 reads (18%) | catalogued as COSV58682660, COSV58691878; called by muse, mutect2, varscan2
- CES3 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.579); catalogued as rs1208262309; called by muse, mutect2
- CKAP5 | c.5153G>A p.R1718Q (on ENST00000529230 / NM_001008938.4; = p.R1658Q on NM_014756.3) | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1461010068; called by muse, mutect2
- CLEC6A | c.155A>G p.K52R | Missense Mutation (SNP) | VAF 33/333 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV65988159; called by muse, mutect2
- COL28A1 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as rs759741398; called by muse, mutect2
- CRACD | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757452431, COSV51715075, COSV99073095; called by muse, mutect2, varscan2
- CRACDL | c.1711G>T p.A571S | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.774); catalogued as rs754085681; called by mutect2, varscan2
- CRACR2A | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs1316345827; called by muse, mutect2
- CRTC1 | c.1249del p.V417Yfs*94 | Frame Shift Del (DEL) | VAF 17/150 reads (11%) | catalogued as COSV58717066; called by mutect2, pindel, varscan2
- CSPP1 | c.1086C>G p.N362K (on ENST00000676605; = p.N321K on NM_024790.6) | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV51591339; called by muse, mutect2
- CUBN | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as rs762144217; called by muse, mutect2
- DCAF12L1 | c.1251G>T p.W417C | Missense Mutation (SNP) | VAF 62/370 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100948051; called by muse, mutect2, varscan2
- DDX3X | c.382G>A p.D128N (on ENST00000399959; = p.D129N on NM_001356.5) | Missense Mutation (SNP) | VAF 78/515 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.759); catalogued as COSV101302359; called by muse, mutect2, varscan2
- DEPDC1B | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV54009751, COSV54010784; called by muse, mutect2, varscan2
- FABP12 | c.349-2A>G p.X117_splice | Splice Site (SNP) | VAF 46/281 reads (16%) | catalogued as COSV100846570; called by muse, mutect2, varscan2
- FAM216B | c.35G>T p.W12L | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.025); catalogued as COSV100573033; called by muse, mutect2, varscan2
- FAM47A | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV60497779; called by muse, mutect2, varscan2
- FAM47C | c.1184C>G p.P395R | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV63728368; called by muse, mutect2
- FBN2 | c.3968G>C p.C1323S | Missense Mutation (SNP) | VAF 65/553 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV52554040; called by muse, mutect2, varscan2
- FBN3 | c.3645G>T p.M1215I | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54475447; called by muse, mutect2, varscan2
- FBXO47 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.116); catalogued as rs1478055792, COSV65241965; called by muse, mutect2, varscan2
- FOXE3 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as rs1170907926; called by muse, mutect2, varscan2
- FSCB | c.2262G>T p.E754D | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.136); catalogued as rs765630575; called by muse, mutect2, varscan2
- GLI3 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 41/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs532044840; called by muse, mutect2, varscan2
- GRIN2A | c.2146G>C p.A716P | Missense Mutation (SNP) | VAF 46/654 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM138252, COSV58032355, COSV58060561; called by muse, mutect2
- GRIN2A | c.502C>A p.H168N | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.137); catalogued as rs1266794502; called by muse, mutect2, varscan2
- HIF1A | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs752063685; called by muse, mutect2, varscan2
- HRNR | c.8389G>T p.G2797C | Missense Mutation (SNP) | VAF 42/632 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.712); catalogued as COSV64263772; called by muse, mutect2
- HSD17B14 | c.163G>T p.G55* | Nonsense Mutation (SNP) | VAF 29/215 reads (13%) | catalogued as COSV54362076; called by muse, mutect2, varscan2
- HSF5 | c.926C>G p.A309G | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs142819367; called by muse, mutect2, varscan2
- IGF2BP3 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51694824; called by muse, mutect2, varscan2
- IGLV8-61 | c.146G>C p.S49T | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as rs373253306, COSV66503062; called by muse, mutect2
- ITGB2 | c.1339G>T p.E447* (on ENST00000302347; = p.E423* on NM_000211.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/362 reads (7%) | catalogued as COSV56612305; called by muse, mutect2
- JAG2 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs140376952; called by muse, mutect2, varscan2
- KCNA4 | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV60254108; called by muse, mutect2, varscan2
- KCNB1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.573); catalogued as COSV65571221; called by muse, mutect2, varscan2
- KCNG1 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV65368140; called by muse, mutect2
- KCNG2 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161088582; called by muse, mutect2
- L1CAM | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 74/465 reads (16%) | catalogued as CM970854; called by muse, mutect2, varscan2
- LRP2 | c.2639+1G>T p.X880_splice | Splice Site (SNP) | VAF 64/468 reads (14%) | catalogued as COSV55557161; called by muse, mutect2, varscan2
- MOB3C | c.488T>A p.V163D | Missense Mutation (SNP) | VAF 46/571 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54718238; called by muse, mutect2
- MUC5B | c.14294C>A p.P4765Q | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); catalogued as COSV71591677; called by muse, mutect2, varscan2
- MYO15A | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 49/337 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.295); catalogued as rs1434822257; called by muse, mutect2, varscan2
- MYPN | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV62732038, COSV62738558; called by muse, mutect2
- NAAA | c.820C>A p.L274I | Missense Mutation (SNP) | VAF 22/355 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV54432577; called by muse, mutect2
- NAV3 | c.2372C>G p.S791C | Missense Mutation (SNP) | VAF 31/364 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV57088080, COSV99887878; called by muse, mutect2
- NPHP4 | c.3854G>C p.G1285A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.235); catalogued as rs1192199886, COSV65395172; called by muse, mutect2
- OR4C46 | c.756C>A p.C252* | Nonsense Mutation (SNP) | VAF 30/260 reads (12%) | catalogued as COSV100060650; called by muse, mutect2, varscan2
- OR4M1 | c.455del p.G152Afs*6 | Frame Shift Del (DEL) | VAF 54/435 reads (12%) | catalogued as rs760267821, COSV60064156; called by mutect2, pindel, varscan2
- OR4M1 | c.940T>A p.*314Rext*? | Nonstop Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV60059571; called by muse, mutect2, varscan2
- OR5D18 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 34/686 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs776032885; called by muse, mutect2
- OR6K2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 64/648 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62743115; called by muse, mutect2
- PAH | c.1118C>A p.A373D | Missense Mutation (SNP) | VAF 77/563 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as CD941752, CM142216, COSV61017133; called by muse, mutect2, varscan2
- PATJ | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57160836; called by muse, mutect2
- PCDH15 | c.4812G>C p.E1604D | Missense Mutation (SNP) | VAF 117/854 reads (14%) | SIFT deleterious, low confidence (0.04); catalogued as COSV64692647; called by muse, mutect2, varscan2
- PCDHA10 | c.1488del p.R497Gfs*38 | Frame Shift Del (DEL) | VAF 76/670 reads (11%) | catalogued as COSV56501540; called by pindel, varscan2
- PCDHA4 | c.2225C>A p.S742Y | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as rs1428831386; called by muse, mutect2, varscan2
- PDE1A | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV59518783; called by muse, mutect2
- PDE1B | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 53/388 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99673125; called by muse, mutect2, varscan2
- PDLIM3 | c.362C>A p.A121E (on ENST00000284770 / NM_001257963.1; = p.A288E on NM_014476.6) | Missense Mutation (SNP) | VAF 38/515 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as rs756453272, COSV52980514; called by muse, mutect2
- PLB1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.269); catalogued as COSV59832507; called by muse, mutect2
- PLCB1 | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 26/172 reads (15%) | catalogued as COSV62042026, COSV62048712; called by muse, mutect2
- POGLUT1 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1000750271, COSV99809934; called by muse, mutect2
- PPP4R3C | c.2468C>A p.S823Y | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as COSV69081097; called by muse, mutect2
- PTGIS | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as rs13306027, COSV99720705; called by muse, mutect2
- RAB3GAP2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 33/616 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs747224775, COSV52964695; ClinVar: uncertain significance; called by muse, mutect2
- RGS7 | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 27/519 reads (5%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.482); catalogued as COSV100471511; called by muse, mutect2
- RNASE10 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV60518453; called by muse, mutect2, varscan2
- RNASE10 | c.491G>C p.G164A | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV60517634; called by muse, mutect2, varscan2
- RP1L1 | c.1805C>T p.T602M | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs752031060; called by muse, mutect2
- RTL1 | c.2734C>A p.P912T | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV101128367; called by muse, mutect2, varscan2
- RYR1 | c.8137G>T p.D2713Y | Missense Mutation (SNP) | VAF 62/434 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62110442; called by muse, mutect2
- RYR2 | c.331C>G p.R111G | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs770848098, COSV63713720; called by muse, mutect2
- SDK1 | c.570G>T p.M190I | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as rs767741124; called by muse, mutect2
- SHOX | c.738C>A p.F246L | Missense Mutation (SNP) | VAF 22/379 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV61860775; called by muse, mutect2
- SLC2A14 | c.1148A>G p.Y383C | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as rs769916495; called by muse, mutect2
- SLITRK2 | c.2353G>T p.A785S | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV59429069; called by muse, mutect2, varscan2
- SNRPN | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 56/373 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100578232; called by muse, mutect2, varscan2
- SORCS3 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV63803612; called by muse, mutect2
- STAG2 | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1214610561; called by muse, mutect2, varscan2
- STXBP6 | c.458G>T p.S153I | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.659); catalogued as COSV60592923; called by muse, mutect2, varscan2
- SV2B | c.297G>T p.M99I | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57701843; called by mutect2, varscan2
- TAF4B | c.2263C>A p.R755S | Missense Mutation (SNP) | VAF 20/347 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52302528; called by muse, mutect2
- TBX22 | c.165C>A p.S55R | Missense Mutation (SNP) | VAF 57/550 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100960979, COSV64786362; called by muse, mutect2, varscan2
- TCF23 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 55/380 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99940353; called by muse, mutect2, varscan2
- TDRD6 | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV60175155; called by muse, mutect2, varscan2
- TFDP3 | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs1228729650, COSV59537468; called by muse, mutect2
- TMEM132C | c.3191del p.P1064Rfs*8 | Frame Shift Del (DEL) | VAF 16/196 reads (8%) | catalogued as rs755317217; called by mutect2, pindel
- TMEM229A | c.827C>A p.T276K | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1370177860; called by muse, mutect2, varscan2
- TMPRSS11B | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100219327; called by muse, mutect2
- TOP2A | c.464A>G p.E155G | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV70733130; called by muse, mutect2, varscan2
- TP53 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 40/355 reads (11%) | catalogued as CM044725, COSV52746809, COSV52814837, COSV53366474; called by muse, mutect2, varscan2
- TRAF5 | c.219-2A>G p.X73_splice | Splice Site (SNP) | VAF 24/257 reads (9%) | catalogued as rs1403519998; called by muse, mutect2
- TRIM51 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 38/775 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99792405; called by muse, mutect2
- TSC22D2 | c.772A>T p.M258L | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV62623616; called by muse, mutect2, varscan2
- TSEN34 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1412182393; called by muse, mutect2
- TSKS | c.465C>A p.N155K | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1251302333, COSV55873547; called by muse, mutect2, varscan2
- TTN | c.80402C>A p.A26801D (on ENST00000591111; = p.A19377D on NM_003319.4) | Missense Mutation (SNP) | VAF 37/189 reads (20%) | PolyPhen possibly damaging (0.617); catalogued as COSV60346613; called by muse, mutect2, varscan2
- TTYH2 | c.1524G>C p.T508= | Splice Region (SNP) | VAF 40/301 reads (13%) | catalogued as COSV99483042; called by muse, mutect2, varscan2
- TYR | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as CM092591; called by muse, mutect2, varscan2
- UBR5 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 10/301 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as rs1318099870, COSV55293679; called by muse, mutect2
- UBXN6 | c.826G>T p.V276F | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV56671519; called by muse, mutect2, varscan2
- UNC13C | c.4424G>T p.G1475V | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52933541; called by muse, mutect2
- USH2A | c.3529G>T p.G1177C | Missense Mutation (SNP) | VAF 87/824 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs923020422; called by muse, mutect2, varscan2
- WDR97 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.27); catalogued as rs1024942614; called by muse, mutect2
- WWC3 | c.2332G>T p.E778* | Nonsense Mutation (SNP) | VAF 22/218 reads (10%) | catalogued as COSV101080910; called by muse, mutect2
- XYLB | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 39/346 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as rs750766033; called by muse, mutect2, varscan2
- ZFP42 | c.39C>A p.H13Q | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1246097948; called by muse, mutect2
- ZIC1 | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 106/340 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51556041; called by muse, mutect2, varscan2
- ZIC1 | c.1282G>T p.A428S | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.052); catalogued as COSV51551945; called by muse, mutect2, varscan2
- ZNF280C | c.2102G>T p.R701L | Missense Mutation (SNP) | VAF 29/406 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs758892966, COSV100921168, COSV63968573; called by muse, mutect2
- ZNF581 | c.256T>A p.C86S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.228); catalogued as COSV99553185; called by muse, mutect2, varscan2
- ZNF600 | c.1774G>A p.V592M | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.556); catalogued as rs143084110; called by muse, mutect2
- ZNF680 | c.47G>T p.R16M | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.889); catalogued as COSV59013911; called by muse, mutect2
- ZNF700 | c.1175G>A p.C392Y | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54315362; called by muse, mutect2
- ZNF708 | c.1444G>T p.G482C | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV63607261; called by muse, mutect2
- ZNF716 | c.1191C>A p.Y397* | Nonsense Mutation (SNP) | VAF 26/310 reads (8%) | catalogued as rs1210596090; called by muse, mutect2
- ZNF835 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73379757; called by muse, mutect2
- AASDH | c.50G>T p.R17I | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2
- ABL1 | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACACA | c.2248G>T p.G750* | Nonsense Mutation (SNP) | VAF 88/612 reads (14%) | called by muse, mutect2, varscan2
- ACTL9 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- ACYP2 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2
- ADGRA2 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- ADHFE1 | c.836G>T p.S279I | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- AHNAK | c.15659C>T p.P5220L | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AHNAK2 | c.7951C>T p.P2651S | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AJAP1 | c.27C>A p.L9= | Splice Region (SNP) | VAF 25/225 reads (11%) | called by muse, mutect2, varscan2
- AL121899.2 | c.547T>A p.F183I | Missense Mutation (SNP) | VAF 46/448 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- ALG1 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ANK1 | c.3562A>G p.I1188V | Missense Mutation (SNP) | VAF 40/585 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.678); called by muse, mutect2
- ANKRD13C | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD16 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2
- ANO5 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.05); called by muse, mutect2
- APOBEC3F | c.818G>T p.W273L | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARAP2 | c.4472A>T p.Y1491F | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP6 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); called by muse, mutect2
- ARHGEF40 | c.1727A>T p.H576L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ARX | c.859G>T p.G287W | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ARX | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 35/557 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- ASH1L | c.6011C>T p.P2004L | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- ASH1L | c.4049G>T p.R1350I | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ASPSCR1 | c.103-1G>T p.X35_splice | Splice Site (SNP) | VAF 24/205 reads (12%) | called by muse, mutect2, varscan2
- ATP13A2 | c.2251+1G>T p.X751_splice | Splice Site (SNP) | VAF 37/275 reads (13%) | called by muse, mutect2, varscan2
- ATP7A | c.3528G>T p.Q1176H | Missense Mutation (SNP) | VAF 47/375 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AXDND1 | c.1563G>C p.K521N | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.212); called by muse, mutect2
- B4GAT1 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- BCAS3 | c.902A>G p.D301G | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- BEST3 | c.270del p.N91Tfs*8 | Frame Shift Del (DEL) | VAF 29/218 reads (13%) | called by mutect2, pindel, varscan2
- BLM | c.4110A>T p.K1370N | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.062); called by muse, mutect2
- BOD1L1 | c.5956C>T p.Q1986* | Nonsense Mutation (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- BRINP2 | c.1469T>A p.L490Q | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- C12orf50 | c.988del p.E330Rfs*18 | Frame Shift Del (DEL) | VAF 76/654 reads (12%) | called by mutect2, pindel, varscan2
- C16orf71 | c.440T>G p.L147R | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.014); called by muse, mutect2
- C1orf226 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.724); called by muse, mutect2
- C1orf56 | c.553T>A p.W185R | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- C2orf81 | c.1590G>C p.M530I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2
- C4orf54 | c.3820G>T p.E1274* | Nonsense Mutation (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- CA8 | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- CACNA1F | c.2698C>G p.R900G | Missense Mutation (SNP) | VAF 44/586 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CACNA1S | c.4738G>T p.A1580S | Missense Mutation (SNP) | VAF 48/418 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CALHM5 | c.748A>G p.R250G | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CBLL1 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 87/600 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- CCDC168 | c.19802G>C p.R6601T | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CCDC168 | c.5486A>T p.Q1829L | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CCDC178 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC85A | c.855G>T p.L285F | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CCNI2 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2
- CD19 | c.1084G>T p.G362* | Nonsense Mutation (SNP) | VAF 15/276 reads (5%) | called by muse, mutect2
- CDH23 | c.4906C>A p.Q1636K | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- CELSR2 | c.7395C>G p.Y2465* | Nonsense Mutation (SNP) | VAF 32/293 reads (11%) | called by muse, mutect2, varscan2
- CERS2 | c.1141T>A p.*381Rext*12 | Nonstop Mutation (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2
- CLCN1 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 57/492 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CLEC4F | c.134T>A p.M45K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2
- CLNS1A | c.162C>G p.F54L | Missense Mutation (SNP) | VAF 24/299 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2
- CNKSR2 | c.65-1G>T p.X22_splice | Splice Site (SNP) | VAF 18/342 reads (5%) | called by muse, mutect2
- COL25A1 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COLEC11 | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CUL7 | c.3604G>A p.A1202T | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CWC27 | c.1341T>A p.Y447* | Nonsense Mutation (SNP) | VAF 18/296 reads (6%) | called by muse, mutect2
- CXCR3 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CXorf66 | c.488G>T p.R163M | Missense Mutation (SNP) | VAF 62/500 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CYP26A1 | c.1057C>A p.L353I | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- DACH2 | c.1664G>T p.S555I | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- DCC | c.1120A>G p.S374G | Missense Mutation (SNP) | VAF 35/333 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- DDX42 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.093); called by muse, mutect2
- DGAT2L6 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 66/566 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH3 | c.4499G>T p.S1500I | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- EFCAB8 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 10/261 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); called by muse, mutect2
- ELMOD1 | c.524G>C p.G175A | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ENAM | c.3014A>G p.N1005S | Missense Mutation (SNP) | VAF 42/590 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.172); called by muse, mutect2
- EPHA1 | c.2867T>C p.M956T | Missense Mutation (SNP) | VAF 49/375 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- EPPK1 | c.684G>C p.L228F | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- EPRS1 | c.4245-1G>A p.X1415_splice | Splice Site (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- ERVV-2 | c.585G>T p.R195S | Missense Mutation (SNP) | VAF 62/582 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ETS1 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2
- EXO1 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- F11 | c.219-8A>G | Splice Region (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- FAM178B | c.235G>C p.A79P | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- FANCA | c.722T>C p.M241T | Missense Mutation (SNP) | VAF 34/494 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2
- FGD5 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FLI1 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FLNC | c.7772A>T p.K2591M | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FLT3 | c.1760A>T p.N587I | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2
- FMN2 | c.2432C>A p.P811Q | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- FOXF1 | c.267C>A p.Y89* | Nonsense Mutation (SNP) | VAF 33/439 reads (8%) | called by muse, mutect2
- FURIN | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- GALNT13 | c.216G>C p.E72D | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT7 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 11/184 reads (6%) | called by muse, mutect2
- GATAD2A | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 35/258 reads (14%) | called by muse, mutect2, varscan2
- GDF6 | c.914del p.P305Rfs*57 | Frame Shift Del (DEL) | VAF 29/118 reads (25%) | called by mutect2, pindel, varscan2
- GIMD1 | c.154A>T p.S52C | Missense Mutation (SNP) | VAF 45/396 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GLG1 | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); called by muse, mutect2
- GMCL2 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR141 | c.547T>A p.Y183N | Missense Mutation (SNP) | VAF 19/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPRASP2 | c.1400C>A p.P467H | Missense Mutation (SNP) | VAF 52/490 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRIA3 | c.26A>G p.Q9R | Missense Mutation (SNP) | VAF 64/585 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRID1 | c.1143G>T p.M381I | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- GRM5 | c.869T>A p.M290K | Missense Mutation (SNP) | VAF 60/469 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSPT2 | c.750G>C p.W250C | Missense Mutation (SNP) | VAF 33/643 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GSX2 | c.481G>C p.A161P | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.202); called by muse, mutect2
- H2AC4 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2
- HBB | c.236T>A p.L79Q | Missense Mutation (SNP) | VAF 64/571 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HDHD3 | c.50C>G p.T17R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD4 | c.4972G>T p.G1658C | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECW1 | c.2500+1G>C p.X834_splice | Splice Site (SNP) | VAF 36/283 reads (13%) | called by muse, mutect2, varscan2
- HEPH | c.2815A>T p.N939Y (on ENST00000343002; = p.N672Y on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/427 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HNF4G | c.940A>G p.M314V (on ENST00000354370 / NM_001330561.2; = p.M361V on NM_004133.5) | Missense Mutation (SNP) | VAF 53/443 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA8 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 61/444 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- IFT57 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- IGHV3-20 | c.343T>C p.C115R | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- IGHV4-39 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 71/623 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- IGKV3-20 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 42/658 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGLV1-50 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IMMT | c.44A>T p.Q15L | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP4A | c.1417G>T p.G473W | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, varscan2
- INVS | c.2761G>T p.A921S | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ITGA8 | c.1531G>T p.D511Y | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2
- ITIH6 | c.729G>T p.M243I | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNA1 | c.101A>T p.E34V | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.141); called by muse, mutect2
- KCNQ3 | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 78/829 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2
- KCNQ4 | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- KDM6A | c.3500T>A p.F1167Y | Missense Mutation (SNP) | VAF 84/561 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA0319 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- KIF1A | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF21A | c.2134G>T p.E712* (on ENST00000361418 / NM_001378440.1; = p.E699* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/394 reads (12%) | called by muse, mutect2, varscan2
- KIR2DL3 | c.693del p.T232Lfs*16 | Frame Shift Del (DEL) | VAF 19/155 reads (12%) | called by mutect2, varscan2
- KMT2C | c.4700G>T p.G1567V | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- KMT2C | c.4699G>T p.G1567* | Nonsense Mutation (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- KRTAP10-5 | c.389G>A p.C130Y | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2
- KRTAP10-9 | c.33C>A p.S11R | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- LGR5 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2
- LRFN5 | c.774T>A p.D258E | Missense Mutation (SNP) | VAF 73/459 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRIG3 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2
- LRP2 | c.2200G>C p.V734L | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- LRRC14B | c.205G>C p.G69R | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.204); called by muse, mutect2
- LRRC66 | c.2264A>G p.E755G | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- LRRC8B | c.1227dup p.L410Tfs*4 | Frame Shift Ins (INS) | VAF 44/303 reads (15%) | called by mutect2, pindel, varscan2
- LRRK1 | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2
- LTBP4 | c.635A>G p.D212G (on ENST00000308370 / NM_001042544.1; = p.D175G on NM_003573.2) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- LZTR1 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- MACF1 | c.9538G>T p.E3180* | Nonsense Mutation (SNP) | VAF 39/261 reads (15%) | called by muse, mutect2, varscan2
- MAGEB6 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 36/550 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- MAGED1 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 29/348 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2
- MAP7 | c.1458G>T p.K486N | Missense Mutation (SNP) | VAF 36/360 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2
- MCF2 | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- MET | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- METTL6 | c.146A>T p.Y49F | Missense Mutation (SNP) | VAF 73/462 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MGAM | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MOG | c.339G>T p.R113S | Missense Mutation (SNP) | VAF 64/403 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MPP1 | c.320G>T p.R107I | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MPZ | c.433T>C p.Y145H | Missense Mutation (SNP) | VAF 56/506 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- MRC1 | c.4028G>C p.S1343T | Missense Mutation (SNP) | VAF 42/642 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2
- MRGPRX3 | c.49G>T p.G17* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2
- MS4A12 | c.415-1G>T p.X139_splice | Splice Site (SNP) | VAF 38/278 reads (14%) | called by muse, mutect2, varscan2
- MS4A18 | c.14T>G p.V5G | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- MTFR1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 27/492 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTUS2 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- MUC12 | c.13323A>C p.E4441D (on ENST00000379442; = p.E4298D on NM_001164462.1) | Missense Mutation (SNP) | VAF 50/381 reads (13%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MUC16 | c.32479C>T p.H10827Y | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MYH6 | c.1506C>A p.Y502* | Nonsense Mutation (SNP) | VAF 61/498 reads (12%) | called by muse, mutect2, varscan2
- MYO6 | c.3835A>T p.R1279* (on ENST00000369981; = p.R1269* on NM_004999.4) | Nonsense Mutation (SNP) | VAF 78/633 reads (12%) | called by muse, mutect2, varscan2
- MYRFL | c.2647-2A>T p.X883_splice | Splice Site (SNP) | VAF 46/259 reads (18%) | called by muse, mutect2, varscan2
- NANOG | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 20/227 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- NCF1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NDST4 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.103); called by muse, mutect2
- NECTIN1 | c.515G>A p.C172Y | Missense Mutation (SNP) | VAF 37/594 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEFM | c.2642A>T p.Q881L | Missense Mutation (SNP) | VAF 28/564 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- NLGN3 | c.2291C>G p.A764G (on ENST00000358741 / NM_181303.2; = p.A744G on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NOMO1 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 37/640 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NRG3 | c.1839G>T p.M613I (on ENST00000404547 / NM_001370084.1; = p.M589I on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/626 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- OLAH | c.487C>T p.P163S (on ENST00000378228 / NM_001039702.3; = p.P216S on NM_018324.3) | Missense Mutation (SNP) | VAF 17/404 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2
- OR10K2 | c.904T>A p.C302S | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- OR10V1 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 27/440 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- OR2M5 | c.382C>A p.H128N | Missense Mutation (SNP) | VAF 43/523 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2
- OR2M7 | c.414del p.I140Ffs*5 | Frame Shift Del (DEL) | VAF 40/370 reads (11%) | called by mutect2, varscan2
- OR5AU1 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- OR5J2 | c.359A>T p.Y120F | Missense Mutation (SNP) | VAF 57/354 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR5L2 | c.100A>C p.I34L | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.327); called by muse, mutect2
- OR9Q2 | c.116T>C p.M39T | Missense Mutation (SNP) | VAF 39/381 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSER1 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 40/426 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- P2RX3 | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAPPA | c.2589G>T p.E863D | Missense Mutation (SNP) | VAF 62/436 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PARD3 | c.1300G>C p.A434P | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- PARP8 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 20/227 reads (9%) | called by muse, mutect2
- PCCA | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 110/657 reads (17%) | called by muse, mutect2, varscan2
- PCDH10 | c.1276G>T p.G426W | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2
- PCDH15 | c.3446A>T p.Y1149F | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCSK2 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 75/566 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- PDHA1 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- PHF3 | c.3673G>T p.A1225S | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PHKB | c.1004G>C p.R335T | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- PIP5K1A | c.1571A>T p.E524V (on ENST00000368888 / NM_001135638.2; = p.E511V on NM_003557.3) | Missense Mutation (SNP) | VAF 51/388 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PKD2L1 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- PLA2G4F | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- PLCB4 | c.1699A>T p.T567S | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLCZ1 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 48/522 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2
- PNLIP | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2
- POC1B-GALNT4 | c.194del p.P65Lfs*23 | Frame Shift Del (DEL) | VAF 50/523 reads (10%) | called by mutect2, pindel
- POSTN | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 62/432 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PPFIA4 | c.2797A>G p.S933G (on ENST00000447715; = p.S934G on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); called by muse, mutect2
- PPP1R13B | c.2777A>G p.H926R | Missense Mutation (SNP) | VAF 27/309 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRB4 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); called by muse, mutect2
- PRKDC | c.1497G>C p.K499N | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PRR5 | c.403T>A p.Y135N (on ENST00000336985 / NM_181333.4; = p.Y126N on NM_015366.4) | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PRRC2C | c.1521G>T p.R507S (on ENST00000367742; = p.R505S on NM_015172.4) | Missense Mutation (SNP) | VAF 56/430 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PSG2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 43/508 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRB | c.389T>A p.V130D | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- PTPRF | c.3143A>G p.Y1048C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QRICH1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- R3HDM2 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 45/442 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- R3HDML | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.104); called by muse, mutect2
- RADIL | c.2566C>A p.P856T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by mutect2, varscan2
- RASGRP2 | c.814-3C>A | Splice Region (SNP) | VAF 21/378 reads (6%) | called by muse, mutect2
- RET | c.2352C>G p.H784Q | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS11 | c.1150C>A p.P384T (on ENST00000397770 / NM_183337.3; = p.P363T on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- RGS7 | c.542G>A p.R181K | Missense Mutation (SNP) | VAF 64/945 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- ROBO2 | c.2620A>G p.M874V | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- RRP12 | c.979A>G p.S327G | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2
- RTN4RL2 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 32/384 reads (8%) | called by muse, mutect2
- RYR2 | c.10442G>T p.C3481F | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCIN | c.1357T>A p.S453T (on ENST00000297029 / NM_001112706.3; = p.S206T on NM_033128.3) | Missense Mutation (SNP) | VAF 45/475 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SCML2 | c.1775A>G p.K592R | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- SERPINB7 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- SGMS2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, mutect2
- SHC2 | c.1111-1G>T p.X371_splice | Splice Site (SNP) | VAF 28/196 reads (14%) | called by muse, mutect2, varscan2
- SHROOM2 | c.4187C>T p.S1396F | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- SHROOM4 | c.2186C>A p.S729Y | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2
- SI | c.5465T>C p.I1822T | Missense Mutation (SNP) | VAF 140/384 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC25A6 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- SLC32A1 | c.711del p.V238Cfs*45 | Frame Shift Del (DEL) | VAF 37/324 reads (11%) | called by mutect2, pindel, varscan2
- SLC35G1 | c.642G>T p.M214I (on ENST00000427197 / NM_001134658.3; = p.M213I on NM_153226.4) | Missense Mutation (SNP) | VAF 25/396 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC38A5 | c.1320C>A p.A440= | Splice Region (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- SLC4A5 | c.3155T>A p.I1052N | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SLITRK5 | c.899T>G p.L300W | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SNAI2 | c.593G>T p.W198L | Missense Mutation (SNP) | VAF 36/555 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPEN | c.8908A>T p.T2970S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.122); called by muse, mutect2
- SPTBN5 | c.1575G>C p.Q525H | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.085); called by muse, mutect2
- SRRT | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 48/406 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SSX5 | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- STC1 | c.325C>A p.L109I | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- SULF2 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TAF15 | c.1487G>T p.G496V (on ENST00000605844 / NM_139215.3; = p.G493V on NM_003487.4) | Missense Mutation (SNP) | VAF 53/449 reads (12%) | PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TBX22 | c.469C>A p.H157N | Missense Mutation (SNP) | VAF 40/700 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TCN2 | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 12/277 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.391); called by muse, mutect2
- TDRD15 | c.3393A>G p.I1131M | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TENM2 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 91/616 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TENM4 | c.5715G>T p.M1905I | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.885); called by muse, mutect2
- TEX15 | c.2230del p.Q744Sfs*51 (on ENST00000256246; = p.Q1127Sfs*51 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 23/219 reads (11%) | called by mutect2, pindel, varscan2
- THAP12 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- TKTL1 | c.1345C>A p.P449T | Missense Mutation (SNP) | VAF 42/432 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2
- TMEM145 | c.670A>C p.I224L | Missense Mutation (SNP) | VAF 42/353 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TMEM185A | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 46/442 reads (10%) | called by muse, mutect2, varscan2
- TMEM38B | c.680A>T p.Q227L | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TNFAIP6 | c.187G>C p.G63R | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFSF14 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM50 | c.278G>C p.R93P | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); called by muse, mutect2
- TRO | c.3998C>A p.T1333N | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- TRPC5 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC6 | c.2581A>T p.R861W | Missense Mutation (SNP) | VAF 70/601 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TTC6 | c.84G>T p.M28I (on ENST00000267368; = p.M1297I on NM_001310135.3) | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TTN | c.11255A>T p.Q3752L (on ENST00000591111; = p.Q3706L on NM_003319.4) | Missense Mutation (SNP) | VAF 86/585 reads (15%) | called by muse, mutect2, varscan2
- UBE3C | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 28/255 reads (11%) | called by muse, mutect2, varscan2
- URB2 | c.2619C>A p.N873K | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USH2A | c.784+1G>T p.X262_splice | Splice Site (SNP) | VAF 35/344 reads (10%) | called by muse, mutect2, varscan2
- VAT1L | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- VPS50 | c.2012G>T p.R671I | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2
- XIAP | c.958C>G p.H320D | Missense Mutation (SNP) | VAF 56/596 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- XKRX | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 125/595 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZBTB33 | c.1757T>C p.L586S | Missense Mutation (SNP) | VAF 46/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZBTB46 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZC3H18 | c.749A>G p.N250S | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZMAT1 | c.449A>T p.K150M | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF268 | c.2613A>C p.K871N | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2
- ZNF28 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2
- ZNF354C | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ZNF398 | c.1672del p.Q558Sfs*55 (on ENST00000475153 / NM_170686.3; = p.Q387Sfs*55 on NM_020781.4) | Frame Shift Del (DEL) | VAF 34/274 reads (12%) | called by mutect2, pindel, varscan2
- ZNF446 | c.1101del p.E369Kfs*245 | Frame Shift Del (DEL) | VAF 29/174 reads (17%) | called by mutect2, pindel, varscan2
- ZNF675 | c.1523A>T p.Y508F | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.39); called by muse, mutect2
- ZNF763 | c.737A>G p.H246R (on ENST00000358987 / NM_001367172.2; = p.H249R on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF786 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2
- ZP4 | c.1405G>T p.D469Y | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ZSCAN1 | c.973T>A p.C325S | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZZEF1 | c.6021G>C p.K2007N | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- ADGRB1 | c.681C>A p.P227= | Silent (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- AGT | c.1119T>C p.S373= | Silent (SNP) | VAF 37/317 reads (12%) | called by muse, mutect2, varscan2
- AHNAK2 | c.14028T>C p.D4676= | Silent (SNP) | VAF 30/203 reads (15%) | called by muse, mutect2, varscan2
- AKAP4 | c.1152T>C p.D384= | Silent (SNP) | VAF 29/292 reads (10%) | catalogued as rs1557203984; called by muse, mutect2
- ALPG | c.492G>T p.V164= | Silent (SNP) | VAF 59/331 reads (18%) | called by muse, mutect2, varscan2
- ANKK1 | c.1527G>T p.L509= | Silent (SNP) | VAF 19/150 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.1485C>A p.A495= (on ENST00000383472 / NM_001366230.1; = p.A336= on NM_001010000.3) | Silent (SNP) | VAF 39/586 reads (7%) | catalogued as COSV99148429; called by muse, mutect2
- AWAT1 | c.303G>T p.G101= | Silent (SNP) | VAF 51/357 reads (14%) | called by muse, mutect2, varscan2
- BVES | c.462C>A p.T154= | Silent (SNP) | VAF 60/466 reads (13%) | called by muse, mutect2, varscan2
- C1orf74 | c.570A>G p.G190= | Silent (SNP) | VAF 68/529 reads (13%) | called by muse, mutect2, varscan2
- CADPS | c.1086C>A p.G362= | Silent (SNP) | VAF 120/661 reads (18%) | catalogued as COSV51890773; called by muse, mutect2, varscan2
- CCDC81 | c.177C>T p.F59= | Silent (SNP) | VAF 46/395 reads (12%) | catalogued as COSV53577629; called by muse, mutect2, varscan2
- CD5 | c.48G>A p.G16= | Silent (SNP) | VAF 29/276 reads (11%) | called by muse, mutect2, varscan2
- CDH12 | c.2163A>C p.L721= | Silent (SNP) | VAF 56/504 reads (11%) | called by muse, mutect2, varscan2
- CDH13 | c.195C>T p.R65= | Silent (SNP) | VAF 21/318 reads (7%) | called by muse, mutect2
- COL13A1 | c.483C>A p.P161= | Silent (SNP) | VAF 25/213 reads (12%) | catalogued as rs1466529801; called by muse, mutect2, varscan2
- COL28A1 | c.1230A>T p.P410= | Silent (SNP) | VAF 42/282 reads (15%) | called by muse, mutect2, varscan2
- COL4A6 | c.4788C>T p.S1596= | Silent (SNP) | VAF 46/372 reads (12%) | catalogued as rs1332804922; called by muse, mutect2, varscan2
- CROT | c.183G>T p.G61= | Silent (SNP) | VAF 40/279 reads (14%) | catalogued as COSV58974102; called by muse, mutect2, varscan2
- CUBN | c.7590G>T p.V2530= | Silent (SNP) | VAF 43/565 reads (8%) | catalogued as COSV64709800; called by muse, mutect2
- DOCK8 | c.4162C>A p.R1388= | Silent (SNP) | VAF 53/478 reads (11%) | catalogued as CM153400; called by muse, mutect2, varscan2
- F8 | c.4101C>A p.T1367= | Silent (SNP) | VAF 29/123 reads (24%) | called by muse, mutect2, varscan2
- FAM110B | c.846A>G p.G282= | Silent (SNP) | VAF 29/503 reads (6%) | called by muse, mutect2
- FAM120C | c.810C>T p.P270= | Silent (SNP) | VAF 40/676 reads (6%) | catalogued as rs782194867; called by muse, mutect2
- FAT4 | c.9117T>C p.D3039= | Silent (SNP) | VAF 12/187 reads (6%) | called by muse, mutect2
- FCGBP | c.12075G>C p.R4025= | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- FFAR3 | c.252C>A p.P84= | Silent (SNP) | VAF 38/726 reads (5%) | called by muse, mutect2
- FMNL3 | c.408G>T p.L136= | Silent (SNP) | VAF 35/370 reads (9%) | called by muse, mutect2, varscan2
- FSHR | c.618A>G p.L206= | Silent (SNP) | VAF 62/682 reads (9%) | catalogued as rs780991313; called by muse, mutect2
- GJD4 | c.628C>T p.L210= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- GPR42 | c.879G>A p.R293= | Silent (SNP) | VAF 43/425 reads (10%) | called by muse, mutect2, varscan2
- GRAMD4 | c.60T>C p.D20= | Silent (SNP) | VAF 14/179 reads (8%) | called by muse, mutect2
- GRIA4 | c.369T>A p.P123= | Silent (SNP) | VAF 43/772 reads (6%) | called by muse, mutect2
- HIPK4 | c.99G>T p.T33= | Silent (SNP) | VAF 31/254 reads (12%) | called by muse, mutect2, varscan2
- HYDIN | c.11661A>G p.P3887= | Silent (SNP) | VAF 42/436 reads (10%) | called by muse, mutect2
- IDH2 | c.1314C>T p.L438= | Silent (SNP) | VAF 32/461 reads (7%) | catalogued as rs578203629, COSV51563206; called by muse, mutect2
- IPO8 | c.1977A>G p.A659= | Silent (SNP) | VAF 30/254 reads (12%) | catalogued as rs774057399; called by muse, mutect2, varscan2
- IQSEC3 | c.564C>G p.T188= | Silent (SNP) | VAF 13/173 reads (8%) | called by muse, mutect2
- KDM5B | c.268C>T p.L90= | Silent (SNP) | VAF 36/250 reads (14%) | called by muse, mutect2, varscan2
- KIF2B | c.960G>C p.T320= | Silent (SNP) | VAF 51/490 reads (10%) | catalogued as rs1334454186, COSV52129902; called by muse, mutect2, varscan2
- KIR3DL2 | c.696C>A p.P232= | Silent (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- LAMB1 | c.2002C>A p.R668= | Silent (SNP) | VAF 24/314 reads (8%) | called by muse, mutect2
- LAMC3 | c.1452C>T p.G484= | Silent (SNP) | VAF 56/412 reads (14%) | called by muse, mutect2, varscan2
- LGR6 | c.2442G>A p.V814= (on ENST00000367278 / NM_001017403.1; = p.V762= on NM_021636.3) | Silent (SNP) | VAF 28/234 reads (12%) | called by muse, mutect2, varscan2
- LRP5 | c.4269G>T p.P1423= | Silent (SNP) | VAF 31/187 reads (17%) | catalogued as rs139701701; called by muse, mutect2, varscan2
- LRRTM1 | c.853C>T p.L285= | Silent (SNP) | VAF 9/164 reads (5%) | catalogued as COSV54441237; called by muse, mutect2
- MAGEA3 | c.570G>T p.L190= | Silent (SNP) | VAF 52/364 reads (14%) | called by muse, mutect2, varscan2
- MAGEA8 | c.660G>T p.P220= | Silent (SNP) | VAF 20/191 reads (10%) | catalogued as rs45518135, COSV54064502; called by muse, mutect2, varscan2
- MALRD1 | c.5985C>T p.S1995= | Silent (SNP) | VAF 25/443 reads (6%) | called by muse, mutect2
- MAMLD1 | c.1272G>A p.Q424= | Silent (SNP) | VAF 66/688 reads (10%) | catalogued as rs1557406412; called by muse, mutect2
- MC5R | c.561C>A p.I187= | Silent (SNP) | VAF 39/349 reads (11%) | called by muse, mutect2, varscan2
- MEP1A | c.1923C>T p.V641= | Silent (SNP) | VAF 35/437 reads (8%) | catalogued as rs1261139443; called by muse, mutect2
- MROH5 | c.585C>A p.A195= | Silent (SNP) | VAF 23/122 reads (19%) | called by muse, mutect2, varscan2
- MUC6 | c.2844G>A p.G948= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV70144861; called by muse, mutect2, varscan2
- MYBPH | c.663C>T p.S221= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- MYO5A | c.1848T>C p.P616= | Silent (SNP) | VAF 84/592 reads (14%) | called by muse, mutect2, varscan2
- MYO7B | c.3936A>C p.R1312= | Silent (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- NCOR1 | c.5217G>T p.R1739= | Silent (SNP) | VAF 26/179 reads (15%) | called by muse, mutect2, varscan2
- NCS1 | c.249C>T p.S83= | Silent (SNP) | VAF 65/414 reads (16%) | catalogued as rs1417102355, COSV64962461; called by muse, mutect2, varscan2
- NFKB1 | c.2008C>T p.L670= (on ENST00000394820 / NM_001382627.1; = p.L671= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 60/521 reads (12%) | catalogued as COSV99896958; called by muse, mutect2, varscan2
- NPAP1 | c.2175G>T p.L725= | Silent (SNP) | VAF 36/247 reads (15%) | catalogued as rs1451815181; called by muse, mutect2, varscan2
- NSUN2 | c.69C>G p.A23= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as rs1329630948; called by muse, mutect2
- NWD1 | c.2667T>C p.D889= | Silent (SNP) | VAF 30/478 reads (6%) | called by muse, mutect2
- NXPE1 | c.1305C>A p.V435= (on ENST00000424269; = p.V293= on NM_152315.5) | Silent (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- OPHN1 | c.99C>T p.N33= | Silent (SNP) | VAF 41/330 reads (12%) | called by muse, mutect2, varscan2
- OPN3 | c.543G>T p.L181= | Silent (SNP) | VAF 98/711 reads (14%) | called by muse, mutect2, varscan2
- OR2F1 | c.927T>A p.S309= | Silent (SNP) | VAF 11/95 reads (12%) | called by mutect2, varscan2
- OR2L13 | c.816C>A p.I272= | Silent (SNP) | VAF 35/515 reads (7%) | catalogued as COSV100813695, COSV63552030; called by muse, mutect2
- OR2T3 | c.252C>A p.P84= | Silent (SNP) | VAF 17/178 reads (10%) | called by mutect2, varscan2
- OR5A1 | c.483C>A p.I161= | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as COSV57377074; called by muse, mutect2, varscan2
- OTOG | c.2802C>T p.L934= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs1235791218; called by muse, mutect2, varscan2
- OTUD5 | c.144C>A p.G48= | Silent (SNP) | VAF 15/188 reads (8%) | called by muse, mutect2
- PCDHA4 | c.2226C>A p.S742= | Silent (SNP) | VAF 36/283 reads (13%) | called by muse, mutect2, varscan2
- PLXNA3 | c.432G>T p.G144= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- PNPLA6 | c.2200C>A p.R734= (on ENST00000414982 / NM_001166111.2; = p.R686= on NM_006702.5) | Silent (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2, varscan2
- PRR32 | c.780T>C p.T260= | Silent (SNP) | VAF 68/721 reads (9%) | catalogued as rs1366988906; called by muse, mutect2
- PTCHD3 | c.894C>A p.T298= | Silent (SNP) | VAF 56/414 reads (14%) | catalogued as rs564915037, COSV101438796, COSV101438966; called by muse, mutect2, varscan2
- RERGL | c.21C>T p.L7= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- RRP8 | c.189C>T p.D63= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- RTTN | c.2424C>T p.F808= | Silent (SNP) | VAF 37/246 reads (15%) | catalogued as COSV55343840; called by muse, mutect2, varscan2
- SIMC1 | c.840A>G p.P280= (on ENST00000443967 / NM_001308196.1; = p.P299= on NM_001308195.2) | Silent (SNP) | VAF 58/347 reads (17%) | called by muse, mutect2, varscan2
- SKIV2L | c.507A>C p.T169= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- SLC1A7 | c.246C>T p.A82= | Silent (SNP) | VAF 35/250 reads (14%) | called by muse, mutect2, varscan2
- SLC26A4 | c.1449G>A p.V483= | Silent (SNP) | VAF 59/549 reads (11%) | called by muse, mutect2, varscan2
- SLC6A16 | c.2100C>G p.S700= | Silent (SNP) | VAF 57/609 reads (9%) | called by muse, mutect2
- SLFN12 | c.156C>A p.L52= | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as COSV59226990; called by muse, mutect2, varscan2
- SMC1A | c.1455G>T p.G485= | Silent (SNP) | VAF 32/608 reads (5%) | called by muse, mutect2
- SPTA1 | c.3672G>T p.R1224= | Silent (SNP) | VAF 78/715 reads (11%) | catalogued as COSV63757430; called by muse, mutect2, varscan2
- SREK1IP1 | c.72G>C p.L24= | Silent (SNP) | VAF 22/404 reads (5%) | called by muse, mutect2
- TBC1D24 | c.678C>T p.A226= | Silent (SNP) | VAF 50/330 reads (15%) | called by muse, mutect2, varscan2
- TECPR2 | c.3096G>C p.V1032= | Silent (SNP) | VAF 17/248 reads (7%) | called by muse, mutect2
- TENT4A | c.1551G>T p.P517= | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as COSV50097075; called by muse, mutect2, varscan2
- TEX14 | c.3285T>A p.T1095= (on ENST00000240361 / NM_001201457.2; = p.T1089= on NM_198393.4) | Silent (SNP) | VAF 29/603 reads (5%) | called by muse, mutect2
- TGM2 | c.336C>T p.I112= | Silent (SNP) | VAF 36/361 reads (10%) | catalogued as rs750556664, COSV63931163; called by muse, mutect2, varscan2
- TMEM35B | c.177G>T p.L59= | Silent (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- TPO | c.1990C>T p.L664= | Silent (SNP) | VAF 22/398 reads (6%) | catalogued as COSV61093410, COSV61104583; called by muse, mutect2
- TRIM51 | c.1149T>C p.V383= | Silent (SNP) | VAF 38/732 reads (5%) | called by muse, mutect2
- UBE2T | c.147T>C p.G49= | Silent (SNP) | VAF 25/291 reads (9%) | called by muse, mutect2
- USH2A | c.2079C>A p.P693= | Silent (SNP) | VAF 39/387 reads (10%) | catalogued as COSV100237744; called by muse, mutect2
- USP54 | c.2904A>G p.A968= | Silent (SNP) | VAF 41/295 reads (14%) | catalogued as rs984622753; called by muse, mutect2, varscan2
- WDR97 | c.3366G>A p.P1122= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs1450993189; called by muse, mutect2, varscan2
- WNT5B | c.825G>A p.P275= | Silent (SNP) | VAF 17/248 reads (7%) | catalogued as rs774864097, COSV60198469; called by muse, mutect2
- WRN | c.4251C>T p.T1417= | Silent (SNP) | VAF 32/522 reads (6%) | catalogued as rs772748725; ClinVar: likely benign; called by muse, mutect2
- XIRP2 | c.3339A>G p.K1113= (on ENST00000628543; = p.K1288= on NM_152381.6) | Silent (SNP) | VAF 33/187 reads (18%) | called by muse, mutect2, varscan2
- XKR6 | c.1281T>A p.I427= | Silent (SNP) | VAF 44/495 reads (9%) | called by muse, mutect2
- ZAN | c.2139C>T p.S713= | Silent (SNP) | VAF 55/448 reads (12%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.6390C>T p.A2130= | Silent (SNP) | VAF 77/494 reads (16%) | called by muse, mutect2, varscan2
- ZNF208 | c.873C>T p.G291= | Silent (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2, varscan2
- ZNF274 | c.1260G>A p.Q420= (on ENST00000610905; = p.Q315= on NM_016324.3) | Silent (SNP) | VAF 40/618 reads (6%) | catalogued as COSV100465630; called by muse, mutect2
- ZNF28 | c.1137A>T p.G379= | Silent (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- ZNF560 | c.261C>A p.T87= | Silent (SNP) | VAF 28/218 reads (13%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-8369A>G | Intron (SNP) | VAF 113/467 reads (24%) | catalogued as rs1353459087; called by muse, mutect2, varscan2
- AC025048.6 | n.683G>A | RNA (SNP) | VAF 47/355 reads (13%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+3230G>T | Intron (SNP) | VAF 12/354 reads (3%) | called by muse, mutect2
- ACAA2 | chr18:49814257 T>A | 5'Flank (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- AK2 | c.*327G>T | 3'UTR (SNP) | VAF 22/159 reads (14%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700984 A>T | 3'Flank (SNP) | VAF 41/346 reads (12%) | called by muse, mutect2, varscan2
- AP001007.2 | n.148C>A | RNA (SNP) | VAF 25/496 reads (5%) | called by muse, mutect2
- AP003548.1 | n.456G>A | RNA (SNP) | VAF 30/333 reads (9%) | called by muse, mutect2
- AQR | c.76-112C>G | Intron (SNP) | VAF 30/492 reads (6%) | called by muse, mutect2
- ARMCX4 | c.1038+1818C>G | Intron (SNP) | VAF 40/366 reads (11%) | called by muse, mutect2, varscan2
- ATP7B | c.2121+47G>A | Intron (SNP) | VAF 36/384 reads (9%) | called by muse, mutect2
- BIVM-ERCC5 | c.3317-32G>C | Intron (SNP) | VAF 76/458 reads (17%) | called by muse, mutect2, varscan2
- BTNL10 | n.203G>A | RNA (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- CCDC159 | c.-11C>T | 5'UTR (SNP) | VAF 24/370 reads (6%) | catalogued as rs911303163; called by muse, mutect2
- CD1C | c.-12T>A | 5'UTR (SNP) | VAF 30/252 reads (12%) | called by muse, mutect2, varscan2
- CFAP69 | c.2189-58G>C | Intron (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- CNGA3 | c.215+294G>A | Intron (SNP) | VAF 43/285 reads (15%) | called by muse, mutect2, varscan2
- CSF2RA | c.*279G>T | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- EMD | c.265+38C>A | Intron (SNP) | VAF 27/273 reads (10%) | catalogued as rs782008300; called by muse, mutect2, varscan2
- EPS15 | c.1883-27G>T | Intron (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- EYA4 | c.1757-73G>T | Intron (SNP) | VAF 91/732 reads (12%) | called by muse, mutect2, varscan2
- EYS | c.1767-6805G>T | Intron (SNP) | VAF 54/883 reads (6%) | called by muse, mutect2
- FHL2 | c.-107C>T | 5'UTR (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- GANAB | c.*496C>G | 3'UTR (SNP) | VAF 20/222 reads (9%) | catalogued as rs528749214, COSV99641885; called by muse, mutect2
- GATA4 | chr8:11761625 T>C | 3'Flank (SNP) | VAF 19/274 reads (7%) | called by muse, mutect2
- GCSAML | c.-42G>T | 5'UTR (SNP) | VAF 34/338 reads (10%) | called by muse, mutect2, varscan2
- HAS2 | c.*64A>G | 3'UTR (SNP) | VAF 18/275 reads (7%) | called by muse, mutect2
- HEPH | c.-28G>T | 5'UTR (SNP) | VAF 16/301 reads (5%) | called by muse, mutect2
- HLA-V | n.29C>G | RNA (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2
- HSP90AA4P | n.1565T>A | RNA (SNP) | VAF 29/372 reads (8%) | catalogued as rs540276770; called by muse, mutect2
- LINC01804 | n.403C>A | RNA (SNP) | VAF 13/155 reads (8%) | catalogued as rs1374678473; called by muse, mutect2
- LINC02312 | n.473G>A | RNA (SNP) | VAF 39/281 reads (14%) | called by muse, mutect2, varscan2
- MCF2 | c.*22C>T | 3'UTR (SNP) | VAF 20/477 reads (4%) | catalogued as rs1279453246; called by muse, mutect2
- MEG3 | n.1124G>A | RNA (SNP) | VAF 34/295 reads (12%) | catalogued as rs1027470616; called by muse, mutect2, varscan2
- MIR572 | n.38G>C | RNA (SNP) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- MIR587 | n.9C>T | RNA (SNP) | VAF 29/280 reads (10%) | called by muse, mutect2, varscan2
- NMRK2 | c.-35C>T | 5'UTR (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- OSCAR | c.*377C>T | 3'UTR (SNP) | VAF 15/197 reads (8%) | called by muse, mutect2
- PHKB | c.2427+1014G>A | Intron (SNP) | VAF 42/729 reads (6%) | catalogued as COSV100065349; called by muse, mutect2
- PKD1 | c.7489+45C>A | Intron (SNP) | VAF 38/268 reads (14%) | catalogued as rs773353153; called by muse, mutect2, varscan2
- PLCZ1 | c.949+60G>T | Intron (SNP) | VAF 34/388 reads (9%) | called by muse, mutect2
- RGS1 | c.444+21C>G | Intron (SNP) | VAF 33/209 reads (16%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159757 C>A | 5'Flank (SNP) | VAF 20/158 reads (13%) | catalogued as rs77325341; called by muse, varscan2
- RNF17 | c.1240+886G>C | Intron (SNP) | VAF 54/257 reads (21%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1461C>A | RNA (SNP) | VAF 37/269 reads (14%) | called by muse, mutect2, varscan2
- SCUBE1 | c.727+2684C>T | Intron (SNP) | VAF 28/392 reads (7%) | catalogued as rs914712818; called by muse, mutect2
- SNORD115-21 | n.36A>T | RNA (SNP) | VAF 40/382 reads (10%) | called by muse, mutect2, varscan2
- SNORD115-44 | n.73G>T | RNA (SNP) | VAF 38/309 reads (12%) | called by muse, mutect2, varscan2
- SNTB2 | c.581-9811A>G | Intron (SNP) | VAF 24/212 reads (11%) | called by muse, mutect2, varscan2
- SNX13 | c.-169G>T | 5'UTR (SNP) | VAF 21/165 reads (13%) | catalogued as rs1482364172; called by muse, mutect2, varscan2
- SOX5 | chr12:23949675 C>A | 5'Flank (SNP) | VAF 56/493 reads (11%) | called by muse, mutect2, varscan2
- TG | c.5549-1650G>A | Intron (SNP) | VAF 16/342 reads (5%) | called by muse, mutect2
- ZAN | c.7787+28C>A | Intron (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100769396; called by muse, mutect2
- ZFPM2 | n.195G>A | RNA (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- ZNF252P | n.1409A>T | RNA (SNP) | VAF 29/149 reads (19%) | called by muse, mutect2, varscan2
- ZNF684 | c.-18G>T | 5'UTR (SNP) | VAF 31/197 reads (16%) | called by muse, mutect2, varscan2
- ZNF841 | c.-78+7744G>T | Intron (SNP) | VAF 35/226 reads (15%) | called by muse, mutect2, varscan2
- ZNF99 | c.*928G>T | 3'UTR (SNP) | VAF 30/230 reads (13%) | catalogued as rs767513264; called by muse, mutect2, varscan2
